Somatic mutation profile of tumor specimen 0DUME3 from CCDI case PBCKWF, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 3.3 years (1,209 days).
Specimen 0DUME3: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 13fc8167-b34c-42ba-82d7-252d3ee64e62.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DUMDM (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a83704b3-c01e-4a4f-9c98-5b6d75f44099

The open-access MAF lists 20 somatic variants for this specimen: 11 protein-altering or splice-affecting, 1 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Intron 3, 3'UTR 3, Splice Region 2, 5'UTR 2, Nonsense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CD46 | c.1164A>T p.K388N | Missense Mutation (SNP) | VAF 48/311 reads (15%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.007); called by muse, varscan2
- CDV3 | c.627-3T>A | Splice Region (SNP) | VAF 26/95 reads (27%) | called by muse, varscan2
- DMXL1 | c.4445G>A p.G1482E | Missense Mutation (SNP) | VAF 13/241 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- EPRS1 | c.2542G>C p.A848P | Missense Mutation (SNP) | VAF 20/178 reads (11%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.633); called by muse, varscan2
- FER1L6 | c.5042T>A p.L1681* | Nonsense Mutation (SNP) | VAF 21/200 reads (11%) | called by muse, varscan2
- HLTF | c.2692C>G p.Q898E | Missense Mutation (SNP) | VAF 27/364 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); called by muse, mutect2
- PAXIP1 | c.2195G>C p.G732A | Missense Mutation (SNP) | VAF 29/298 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- PPP4R3A | c.521T>A p.L174Q | Missense Mutation (SNP) | VAF 17/199 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by mutect2, varscan2
- THADA | c.636G>T p.Q212H | Missense Mutation (SNP) | VAF 26/236 reads (11%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.956); called by muse, varscan2
- VPS41 | c.1740T>A p.I580= | Splice Region (SNP) | VAF 18/297 reads (6%) | called by muse, mutect2
- ZNF578 | c.1620A>T p.K540N | Missense Mutation (SNP) | VAF 14/118 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, varscan2
- SLCO1B1 | c.657T>A p.G219= | Silent (SNP) | VAF 16/208 reads (8%) | called by muse, mutect2
- BBOF1 | c.*81A>T | 3'UTR (SNP) | VAF 23/222 reads (10%) | called by muse, varscan2
- C15orf40 | c.*63T>A | 3'UTR (SNP) | VAF 26/212 reads (12%) | called by muse, mutect2
- CBX3 | c.*28T>A | 3'UTR (SNP) | VAF 27/208 reads (13%) | catalogued as COSV100523016; called by muse, varscan2
- NRCAM | c.-57C>A | 5'UTR (SNP) | VAF 14/112 reads (13%) | catalogued as rs926414386, COSV100695372; called by muse, varscan2
- RMI1 | c.-9T>A | 5'UTR (SNP) | VAF 27/84 reads (32%) | called by muse, varscan2
- RPF1 | c.366+46G>T | Intron (SNP) | VAF 20/166 reads (12%) | called by muse, mutect2
- TRPA1 | c.1195-74T>A | Intron (SNP) | VAF 4/20 reads (20%) | called by muse, varscan2
- ZFYVE16 | c.3607+79C>T | Intron (SNP) | VAF 4/21 reads (19%) | called by muse, varscan2
